Somatic mutation profile of tumor specimen BA2244D (aliquot aq-BA2244D) from BEATAML1.0 case 2219, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 67.4 years (24,626 days).
Specimen BA2244D: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 16ce30f4-70c9-4b8b-94dd-0ec293e0e7ff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA3000D (Solid Tissue Normal), aliquot aq-BA3000D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/027816d6-9732-4f9e-b148-66e8b52d312d

The open-access MAF lists 7 somatic variants for this specimen: 3 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 3, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>C p.Q61P | Missense Mutation (SNP) | VAF 29/58 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- C6orf52 | c.96G>T p.K32N | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.203); called by muse, mutect2
- SLC4A3 | c.781C>A p.L261M | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, mutect2
- ABHD16B | c.1314C>T p.L438= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as rs1407301772, COSV53861545; called by muse, mutect2, varscan2
- SCN10A | c.2664G>T p.L888= | Silent (SNP) | VAF 3/38 reads (8%) | called by muse, mutect2
- ZNF729 | c.3552A>G p.G1184= | Silent (SNP) | VAF 54/217 reads (25%) | called by muse, mutect2, varscan2
- ACIN1 | c.2298-1835C>T | Intron (SNP) | VAF 32/90 reads (36%) | called by muse, mutect2, varscan2
